Somatic mutation profile of tumor specimen C3N-01419-03 (aliquot CPT0118040009) from CPTAC case C3N-01419, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.7 years (21,422 days).
Specimen C3N-01419-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46e2395d-7b0d-493d-86f2-93252e0ccdaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01419-75 (Blood Derived Normal), aliquot CPT0119310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/576f9c77-82e8-44ae-82da-5fc1851de3e4

The open-access MAF lists 56 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Nonsense Mutation 6, Frame Shift Del 3, Intron 3, In Frame Del 1, 5'UTR 1, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.5084G>A p.R1695H | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs541097917, COSV54126321; called by muse, mutect2, varscan2
- DNAH5 | c.7508G>A p.R2503H | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV54205094, COSV54221228; called by muse, mutect2, varscan2
- ERBB4 | c.3299A>C p.E1100A | Missense Mutation (SNP) | VAF 66/420 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV61533075; called by muse, mutect2, varscan2
- LAMA5 | c.7417C>T p.Q2473* | Nonsense Mutation (SNP) | VAF 20/166 reads (12%) | catalogued as COSV53369670; called by muse, mutect2, varscan2
- MAP1B | c.1246G>T p.G416* | Nonsense Mutation (SNP) | VAF 35/187 reads (19%) | catalogued as COSV57093433; called by muse, mutect2, varscan2
- OR14I1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs376589225; called by muse, mutect2, varscan2
- OR5B17 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs199698092, COSV62159833; called by muse, mutect2, varscan2
- OXR1 | c.122C>T p.P41L (on ENST00000442977 / NM_001198532.1; = p.P40L on NM_018002.3) | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); catalogued as rs767188608; called by muse, mutect2, varscan2
- RFC4 | c.827del p.G276Efs*14 | Frame Shift Del (DEL) | VAF 50/307 reads (16%) | catalogued as rs748046423, COSV56217365, COSV56217929; called by mutect2, pindel, varscan2
- SCN3B | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs765104250, COSV54798251; called by muse, mutect2, varscan2
- SETDB1 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 29/137 reads (21%) | catalogued as COSV54980079, COSV54991418; called by muse, mutect2, varscan2
- SP4 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as rs1193339718; called by mutect2, varscan2
- SSU72 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.775); catalogued as rs1035098957, COSV52219370; called by muse, mutect2, varscan2
- TARS2 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 20/185 reads (11%) | catalogued as rs1199659882, COSV100946100; called by muse, mutect2, varscan2
- TBC1D14 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs960064608; called by muse, mutect2, varscan2
- TOPBP1 | c.4323G>C p.L1441F | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1345898946, COSV53433785, COSV53441997; called by muse, mutect2, varscan2
- UBR4 | c.7474G>A p.V2492I | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.786); catalogued as rs61759877; called by muse, mutect2, varscan2
- ZBTB33 | c.1133C>A p.P378H | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV58533832; called by muse, mutect2, varscan2
- ARMH2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD28 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH8 | c.1890C>G p.C630W | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- DNAH3 | c.8527C>G p.L2843V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GATAD1 | c.287_302del p.R96Nfs*23 | Frame Shift Del (DEL) | VAF 42/255 reads (16%) | called by mutect2, pindel, varscan2
- GCLM | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GFPT2 | c.1809C>G p.C603W | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- IPO8 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- KCNV1 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 60/363 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA3 | c.8824A>G p.T2942A (on ENST00000313654 / NM_198129.4; = p.T1333A on NM_000227.6) | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NSUN2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 87/549 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- P2RX7 | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 131/438 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMC6 | c.274A>T p.R92* (on ENST00000612399; = p.R78* on NM_002806.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- RGSL1 | c.3100C>G p.Q1034E | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SETD2 | c.607_608del p.S203Ifs*33 | Frame Shift Del (DEL) | VAF 32/157 reads (20%) | called by pindel, varscan2
- SH3YL1 | c.199_207del p.I67_V69del | In Frame Del (DEL) | VAF 41/257 reads (16%) | called by mutect2, pindel*, varscan2*
- SOS2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TAPBPL | c.63C>T p.T21= | Splice Region (SNP) | VAF 57/338 reads (17%) | called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2428A>T p.I810F | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSC22D4 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 71/439 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TYW3 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 34/242 reads (14%) | called by muse, mutect2, varscan2
- USH2A | c.4985C>A p.P1662H | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ZNF267 | c.1514C>G p.S505C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- BOD1L1 | c.1587A>G p.S529= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
- EHD4 | c.1548C>T p.D516= | Silent (SNP) | VAF 45/288 reads (16%) | catalogued as rs147692284; called by muse, mutect2, varscan2
- GRID1 | c.3015C>T p.H1005= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs769287013, COSV60016842, COSV60028175; called by muse, mutect2
- KLF8 | c.591C>T p.G197= | Silent (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- MITD1 | c.469C>T p.L157= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs749984024, COSV56805914; called by muse, mutect2, varscan2
- MZT2A | c.348G>A p.G116= | Silent (SNP) | VAF 36/268 reads (13%) | called by muse, mutect2, varscan2
- RAD50 | c.1161A>G p.P387= | Silent (SNP) | VAF 46/405 reads (11%) | called by muse, mutect2, varscan2
- SHANK1 | c.93C>T p.D31= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs764205732, COSV99520023; called by muse, mutect2, varscan2
- ZNF131 | c.330G>A p.E110= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- COL1A1 | c.2398-40C>T | Intron (SNP) | VAF 44/241 reads (18%) | called by muse, mutect2, varscan2
- GOSR2 | chr17:46940532 G>A | 3'Flank (SNP) | VAF 64/463 reads (14%) | catalogued as rs369557972; called by muse, mutect2, varscan2
- MTA2 | c.958-9T>G | Intron (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- REG1B | c.-7G>A | 5'UTR (SNP) | VAF 29/123 reads (24%) | catalogued as rs202197145; called by muse, mutect2, varscan2
- RUSF1 | c.958+11C>T | Intron (SNP) | VAF 96/448 reads (21%) | called by muse, mutect2, varscan2
- ZBTB25 | c.*6554G>A | 3'UTR (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2, varscan2
